Somatic mutation profile of tumor specimen TCGA-HQ-A2OE-01A (aliquot TCGA-HQ-A2OE-01A-11D-A202-08) from TCGA case TCGA-HQ-A2OE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS.
Specimen TCGA-HQ-A2OE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3fc3cdb-c67a-4a84-b553-d2c65c91890f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HQ-A2OE-10A (Blood Derived Normal), aliquot TCGA-HQ-A2OE-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c3df8c8-eae6-40b4-9be5-7de872de0af6

The open-access MAF lists 169 somatic variants for this specimen: 124 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 40, Nonsense Mutation 11, Splice Site 4, Frame Shift Del 3, In Frame Del 2, Intron 2, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 145/358 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.2112C>G p.F704L | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58129386; called by muse, mutect2, varscan2
- ACBD4 | c.580G>A p.G194R (on ENST00000376955 / NM_001378111.1; = p.R197Q on NM_024722.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs561659128, COSV100416038, COSV58850918; called by muse, mutect2, varscan2
- ADAMTS9 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55776086; called by muse, mutect2, varscan2
- ADGRL2 | c.2912T>C p.I971T (on ENST00000370717 / NM_001366005.1; = p.I958T on NM_012302.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54655166; called by muse, mutect2, varscan2
- AMER3 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV58465389, COSV58469242; called by muse, mutect2, varscan2
- ANKIB1 | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV56059052; called by muse, varscan2
- BAIAP3 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs778099100, COSV60977662; called by muse, mutect2, varscan2
- BAP1 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56231252, COSV56238617; called by muse, mutect2, varscan2
- BAP1 | c.1968G>C p.K656N | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56231263; called by muse, mutect2, varscan2
- BRPF1 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57403430; called by muse, mutect2
- CAMLG | c.700-1G>C p.X234_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV51804366; called by muse, mutect2, varscan2
- CCDC126 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs146283363; called by muse, mutect2, varscan2
- CCDC191 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV55670465; called by mutect2, varscan2
- CCDC28A | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.108); catalogued as COSV60424544; called by mutect2, varscan2
- CCNA1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV55220170; called by muse, mutect2, varscan2
- CCNY | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371273756, COSV55181977; called by muse, mutect2, varscan2
- CEMIP | c.1435G>C p.G479R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV54988866; called by muse, mutect2, varscan2
- CFAP43 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as rs753352553, COSV63852175; called by muse, mutect2, varscan2
- CFAP70 | c.3359C>G p.S1120C | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV60281308; called by muse, mutect2, varscan2
- COL11A2 | c.3802C>G p.P1268A (on ENST00000341947 / NM_080680.3; = p.P1161A on NM_080679.2) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59494073; called by muse, mutect2, varscan2
- COL19A1 | c.494del p.P165Lfs*27 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV59573421; called by mutect2, varscan2
- CTSO | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70808857; called by muse, mutect2, varscan2
- CTTNBP2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200782612, COSV50392485; called by muse, mutect2, varscan2
- CWC27 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV66884246; called by muse, mutect2, varscan2
- DCAF10 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.063); catalogued as rs763749718, COSV54287229; called by muse, mutect2, varscan2
- DCDC2B | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV52207783, COSV52209639; called by muse, mutect2, varscan2
- DCLRE1C | c.389C>G p.T130S (on ENST00000378278 / NM_001350965.2; = p.T15S on NM_022487.4) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100740015, COSV63182063; called by muse, mutect2, varscan2
- DENND1C | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57568007; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1382A>G p.Q461R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV50754149; called by muse, mutect2, varscan2
- FBXO31 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61147856; called by muse, mutect2, varscan2
- FGFR1 | c.1454G>C p.G485A (on ENST00000447712 / NM_023110.3; = p.G483A on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58329117, COSV58346851; called by muse, mutect2, varscan2
- FNBP4 | c.2834C>G p.S945C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55446636; called by muse, mutect2, varscan2
- FOXD4L6 | c.1218C>G p.C406W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.187); catalogued as COSV66223092; called by muse, mutect2, varscan2
- GALR2 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs916768054, COSV57161649; called by muse, mutect2, varscan2
- GBF1 | c.2086G>A p.E696K (on ENST00000369983 / NM_001377137.1; = p.E695K on NM_004193.3) | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV64143139; called by muse, mutect2, varscan2
- GGT7 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV60539904; called by muse, mutect2
- GLIS1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs762587124, COSV56544474; called by muse, mutect2
- GNAT1 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51696646; called by muse, mutect2, varscan2
- GORAB | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV63025941; called by muse, mutect2, varscan2
- HEATR3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs1232796162, COSV53528291; called by muse, mutect2, varscan2
- HNF4G | c.505-2A>T p.X169_splice (on ENST00000354370 / NM_001330561.2; = p.X216_splice on NM_004133.5) | Splice Site (SNP) | VAF 5/14 reads (36%) | catalogued as COSV62966147; called by muse, mutect2
- HPCA | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201103779, COSV65102781; called by muse, mutect2, varscan2
- HPS3 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56053022; called by muse, mutect2, varscan2
- HSP90AB1 | c.2052C>G p.I684M | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV51487909; called by muse, mutect2, varscan2
- IGSF1 | c.3041G>T p.W1014L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.988); catalogued as COSV63836397; called by muse, mutect2, varscan2
- IL19 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54282663, COSV54283243; called by muse, mutect2, varscan2
- IMPG2 | c.1580C>G p.S527C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV51974271, COSV99516485; called by muse, mutect2, varscan2
- INKA2 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV61877182; called by muse, mutect2, varscan2
- IQGAP1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51582029; called by muse, mutect2, varscan2
- ITGB2 | c.1096G>A p.V366M (on ENST00000302347; = p.V342M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs759487369, COSV56608148; called by muse, mutect2, varscan2
- IVNS1ABP | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.28); catalogued as COSV62250627; called by muse, mutect2, varscan2
- JHY | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 29/37 reads (78%) | catalogued as COSV57073707; called by muse, mutect2, varscan2
- KDM5C | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62890815; called by muse, mutect2, varscan2
- KIF15 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV58158846; called by muse, mutect2, varscan2
- KIN | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1306202813, COSV65430028; called by muse, mutect2, varscan2
- KLK15 | c.518G>C p.S173T | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.557); catalogued as COSV56826064; called by muse, mutect2, varscan2
- LAMA2 | c.4744C>G p.L1582V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV70340023; called by muse, mutect2, varscan2
- LRRIQ3 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770132340, COSV100598553, COSV63041590; called by muse, mutect2, varscan2
- MACF1 | c.14335C>T p.L4779F (on ENST00000372915; = p.L2712F on NM_012090.5) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV57109115; called by muse, mutect2, varscan2
- MAGEL2 | c.3745C>G p.R1249G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as rs769676927, COSV58566066, COSV58567423, COSV58567519; called by muse, mutect2, varscan2
- MLXIPL | c.1586C>G p.T529R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57667056; called by muse, mutect2, varscan2
- MSC | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57696195; called by muse, mutect2, varscan2
- NEB | c.15903C>A p.Y5301* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99420008; called by muse, mutect2, varscan2
- NECTIN4 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV63512036; called by muse, mutect2, varscan2
- NKTR | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV51769647; called by muse, mutect2, varscan2
- NLRP13 | c.547A>T p.N183Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV61620304; called by muse, mutect2, varscan2
- NLRP7 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1377290637, COSV60171043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2M7 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs41304034, COSV100522544, COSV58738126; called by muse, mutect2, varscan2
- OR4K5 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60002506; called by muse, mutect2, varscan2
- PDE11A | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53687592; called by muse, mutect2
- PKP2 | c.2146-1G>T p.X716_splice | Splice Site (SNP) | VAF 15/109 reads (14%) | catalogued as CS043144, COSV50726396; called by muse, mutect2, varscan2
- PNPLA7 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1188002417, COSV52994253; called by muse, mutect2
- POM121L12 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as rs991828786, COSV68692350; called by muse, mutect2, varscan2
- PPP1CA | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56701964; called by muse, mutect2, varscan2
- PRKG2 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100019018, COSV52320202; called by muse, mutect2, varscan2
- PRRX2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV100991210; called by muse, mutect2
- PRTG | c.2840C>G p.S947* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101221344; called by muse, mutect2, varscan2
- PSPH | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV51909147; called by muse, varscan2
- RESF1 | c.2662G>C p.D888H | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100440449, COSV57020000; called by muse, mutect2, varscan2
- RSRC2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.182); catalogued as rs768515110, COSV59203696; called by muse, mutect2, varscan2
- RWDD2B | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54501153; called by muse, mutect2, varscan2
- SEC23A | c.957C>G p.D319E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV56971374; called by muse, mutect2, varscan2
- SERINC3 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV54855569; called by muse, mutect2, varscan2
- SLC16A6 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.269); catalogued as rs782692886, COSV59176433; called by muse, mutect2, varscan2
- SLC18B1 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51593498; called by muse, mutect2, varscan2
- SLCO6A1 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753648135, COSV65806186, COSV65815415; called by muse, mutect2, varscan2
- SNAP29 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.604); catalogued as COSV53142128; called by muse, mutect2, varscan2
- SNRNP35 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV63471842; called by muse, mutect2, varscan2
- SPINDOC | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV53692026, COSV53692367; called by muse, mutect2, varscan2
- SRBD1 | c.1352A>T p.K451M | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55396366; called by muse, mutect2, varscan2
- TDRD1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV52587965, COSV99314379; called by muse, mutect2, varscan2
- TEKT5 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs764879505, COSV51586920; called by muse, mutect2, varscan2
- TERB2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100546495, COSV61650556; called by muse, mutect2, varscan2
- TGIF2LX | c.545A>T p.K182M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV52213440; called by muse, mutect2, varscan2
- TMBIM6 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57278701; called by muse, mutect2, varscan2
- TNS3 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as rs370345227, COSV60787468; called by muse, mutect2, varscan2
- VSTM4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs770868197, COSV60524685, COSV60527240; called by muse, mutect2, varscan2
- VWF | c.2145C>G p.I715M | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV54613052, COSV54619851; called by muse, mutect2, varscan2
- WAS | c.962G>C p.R321P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs782802310, COSV64997375; called by muse, mutect2
- WDR93 | c.1085G>A p.C362Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as COSV51530699; called by muse, mutect2, varscan2
- WNK3 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63612340; called by muse, mutect2
- ZMYND19 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1376455967, COSV53811077; called by muse, mutect2, varscan2
- ZNF20 | c.1526A>G p.K509R | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV61998748; called by muse, mutect2, varscan2
- ZNF804B | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60818231; called by muse, mutect2, varscan2
- C1S | c.1275T>A p.C425* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- CEBPB | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- COQ2 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- DUOX1 | c.4042G>C p.E1348Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- IL3RA | c.447C>G p.Y149* | Nonsense Mutation (SNP) | VAF 64/698 reads (9%) | called by muse, mutect2
- ITGA8 | c.2119-3_2133del p.X707_splice | Splice Site (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel
- LIMA1 | c.1655C>G p.S552* | Nonsense Mutation (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- LSM14B | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC3A | c.7034T>C p.I2345T | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- MYLK | c.3844G>T p.E1282* | Nonsense Mutation (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- NUP107 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- PMM2 | c.591_596del p.E197_N198del | In Frame Del (DEL) | VAF 23/217 reads (11%) | called by mutect2, pindel, varscan2
- PRRC1 | c.262dup p.T88Nfs*17 | Frame Shift Ins (INS) | VAF 55/162 reads (34%) | called by mutect2, pindel, varscan2
- PTGER4 | c.1395_1398del p.A466Lfs*15 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- RGL3 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 133/317 reads (42%) | called by muse, mutect2, varscan2
- RHBG | c.21_32del p.A8_R11del | In Frame Del (DEL) | VAF 19/102 reads (19%) | called by pindel, varscan2*
- SPR | c.361_398del p.N121Pfs*21 | Frame Shift Del (DEL) | VAF 48/338 reads (14%) | called by mutect2, pindel
- XRRA1 | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 48/164 reads (29%) | called by muse, varscan2
- APCS | c.75G>C p.G25= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV54817406, COSV54818517; called by muse, mutect2, varscan2
- CARM1 | c.1350C>T p.I450= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV53402838; called by muse, mutect2, varscan2
- CDCA3 | c.279G>A p.L93= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as rs782001440, COSV57528071, COSV57529782; called by muse, mutect2, varscan2
- CELSR2 | c.4941C>T p.R1647= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs760909842, COSV54767687; called by muse, varscan2
- CLPX | c.1413C>T p.D471= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs745631028, COSV55643346; called by muse, mutect2, varscan2
- COL9A3 | c.804C>T p.G268= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs372387045; called by muse, mutect2, varscan2
- COMP | c.1638G>A p.Q546= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1283323900, COSV55873986, COSV99721460; called by muse, varscan2
- DEFA5 | c.284G>A p.*95= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100400400; called by muse, mutect2
- DHX37 | c.75C>T p.P25= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs1232622980, COSV58132390; called by muse, mutect2, varscan2
- DMD | c.2691G>A p.L897= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV63737448; called by muse, mutect2, varscan2
- DNAH9 | c.6243G>A p.K2081= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV52336946, COSV52347981; called by muse, mutect2, varscan2
- FCGR2A | c.702T>A p.A234= (on ENST00000271450 / NM_001136219.3; = p.A233= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as COSV54837346; called by muse, mutect2, varscan2
- FGF18 | c.567C>T p.F189= | Silent (SNP) | VAF 57/67 reads (85%) | catalogued as COSV51125398; called by muse, mutect2, varscan2
- GCN1 | c.8015G>A p.*2672= | Silent (SNP) | VAF 32/303 reads (11%) | called by muse, mutect2, varscan2
- GPRASP2 | c.249T>G p.G83= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV59990405; called by muse, mutect2
- HCK | c.949C>T p.L317= | Silent (SNP) | VAF 76/93 reads (82%) | catalogued as COSV52940630; called by muse, mutect2, varscan2
- HLA-B | c.1002G>A p.R334= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV69520573; called by muse, mutect2, varscan2
- IMPA1 | c.105G>T p.L35= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV56270435; called by muse, mutect2, varscan2
- KIAA0100 | c.5760G>C p.L1920= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV56381186; called by muse, mutect2
- MAGEL2 | c.2091C>G p.P697= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100045753; called by muse, mutect2
- MATN4 | c.960G>T p.R320= (on ENST00000372754; = p.R279= on NM_003833.4) | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV61350479; called by muse, mutect2, varscan2
- MINAR1 | c.1479T>C p.S493= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV59581138; called by muse, mutect2, varscan2
- OR5D18 | c.78C>G p.V26= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61736385; called by muse, mutect2
- PASK | c.3690G>A p.G1230= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV52149433; called by muse, mutect2, varscan2
- PER3 | c.3030A>G p.T1010= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs12023156; called by muse, varscan2
- PLA2G4F | c.1134G>T p.G378= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV51825663; called by muse, mutect2, varscan2
- PLCL2 | c.1947T>C p.N649= (on ENST00000615277 / NM_001144382.2; = p.N523= on NM_015184.5) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV67620771; called by muse, mutect2, varscan2
- PRAMEF14 | c.1323G>C p.L441= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs749767054, COSV58049995; called by muse, mutect2, varscan2
- PRX | c.63G>A p.V21= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- PTCRA | c.771C>G p.L257= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2
- RAG2 | c.1512C>A p.S504= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV57556565; called by muse, mutect2, varscan2
- S1PR5 | c.909C>T p.P303= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV61013363; called by muse, mutect2, varscan2
- SCAI | c.837C>T p.L279= (on ENST00000336505 / NM_001144877.3; = p.L302= on NM_173690.5) | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV60609538, COSV60610306; called by muse, mutect2, varscan2
- SEC14L3 | c.750G>A p.G250= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs146711095; called by muse, mutect2
- SOX9 | c.897G>A p.P299= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs1455014392, COSV55422600; called by muse, mutect2, varscan2
- SPARCL1 | c.963C>T p.L321= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs763096205, COSV56802537; called by muse, mutect2, varscan2
- SPATA33 | c.57C>T p.S19= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53682291; called by muse, mutect2, varscan2
- TTN | c.54435G>A p.L18145= (on ENST00000591111; = p.L10721= on NM_003319.4) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV59911342; called by muse, mutect2, varscan2
- ZNF263 | c.1107G>A p.P369= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs778442540, COSV54595418; called by muse, mutect2, varscan2
- ZNF804A | c.3192G>A p.K1064= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs763862583, COSV56437441; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24050946 G>C | 5'Flank (SNP) | VAF 9/32 reads (28%) | catalogued as rs375471592; called by muse, mutect2, varscan2
- MYBPC1 | c.104-2560G>A | Intron (SNP) | VAF 16/101 reads (16%) | catalogued as COSV62251371; called by muse, mutect2, varscan2
- PHACTR1 | c.664+2158C>G | Intron (SNP) | VAF 71/184 reads (39%) | catalogued as COSV60660474; called by muse, mutect2, varscan2
- SAMD3 | c.*1T>C | 3'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs145284069; called by muse, mutect2, varscan2
- SNORD116-11 | n.55G>T | RNA (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
